Somatic mutation profile of tumor specimen TCGA-DD-AAVQ-01A (aliquot TCGA-DD-AAVQ-01A-11D-A40R-10) from TCGA case TCGA-DD-AAVQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 38.1 years (13,911 days).
Specimen TCGA-DD-AAVQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8e63c78-fe6b-4e36-a217-46574432e722.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAVQ-10A (Blood Derived Normal), aliquot TCGA-DD-AAVQ-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb38ce58-6a3d-45be-ac8a-23d021241a75

The open-access MAF lists 60 somatic variants for this specimen: 48 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 42, Silent 12, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 16/113 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.9961C>T p.R3321* | Nonsense Mutation (SNP) | VAF 23/112 reads (21%) | catalogued as rs793888512, CM105475, COSV56410587; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STXBP1 | c.326-1G>T p.X109_splice | Splice Site (SNP) | VAF 9/77 reads (12%) | catalogued as rs1554776948, COSV100964599; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APEX1 | c.659T>C p.L220P | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99164492; called by muse, mutect2, varscan2
- ATAD2B | c.2378G>T p.R793I | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV99477938; called by muse, mutect2, varscan2
- C1QL3 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100126717; called by muse, mutect2
- CACNA1A | c.224A>T p.N75I | Missense Mutation (SNP) | VAF 262/1037 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100802701; called by muse, mutect2, varscan2
- CALR | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 76/345 reads (22%) | catalogued as COSV100330831; called by muse, mutect2, varscan2
- CAPN11 | c.150G>T p.K50N | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV101291905; called by muse, mutect2, varscan2
- CAVIN2 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV100414232; called by muse, mutect2, varscan2
- CCDC6 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.587); catalogued as COSV99569582; called by muse, mutect2, varscan2
- CLCN6 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100412015; called by muse, mutect2, varscan2
- COL17A1 | c.3376G>T p.D1126Y | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100793216; called by muse, mutect2, varscan2
- CSPG4 | c.6192C>A p.D2064E | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV100413864; called by muse, mutect2
- FCGR2C | c.390G>A p.E130= | Splice Region (SNP) | VAF 50/548 reads (9%) | catalogued as rs551068879, COSV63436155; called by muse, mutect2
- FYB1 | c.972dup p.P325Afs*43 | Frame Shift Ins (INS) | VAF 14/100 reads (14%) | catalogued as rs748874978; called by mutect2, varscan2
- GOLGA7B | c.290A>T p.K97M | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV100085704; called by muse, mutect2, varscan2
- GRB7 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100485562; called by muse, mutect2, varscan2
- GUCY1A1 | c.195T>A p.S65R | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV99637995; called by muse, mutect2, varscan2
- HERC2 | c.10429G>T p.D3477Y | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs1431780967, COSV99874802; called by muse, mutect2, varscan2
- MIDN | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as rs773701369, COSV56297460; called by muse, mutect2, varscan2
- MYOM1 | c.2629A>C p.S877R | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV99867225; called by muse, mutect2
- NYAP2 | c.1103A>G p.N368S | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV99797261; called by muse, mutect2, varscan2
- OR2T12 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 208/425 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.1); catalogued as rs369908991, COSV100528022; called by muse, mutect2, varscan2
- POLR2B | c.1007T>C p.I336T | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as rs1184970784, COSV100108155; called by muse, mutect2
- PRR23B | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.047); catalogued as COSV61494856; called by muse, mutect2, varscan2
- RGMB | c.928C>A p.Q310K (on ENST00000513185 / NM_001366508.1; = p.Q351K on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100374911; called by muse, mutect2
- RIMBP2 | c.1013A>T p.K338M | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV99899805; called by muse, mutect2, varscan2
- RIPOR3 | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99246689; called by muse, mutect2, varscan2
- RWDD2B | c.595A>C p.N199H | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99725642; called by muse, mutect2, varscan2
- SERPINA11 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.838); catalogued as COSV58243265; called by muse, mutect2, varscan2
- SH3BP5L | c.1037A>G p.Q346R | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as COSV100822026; called by muse, mutect2, varscan2
- SLC52A3 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99448090; called by muse, mutect2, varscan2
- SLC52A3 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99448093; called by muse, mutect2, varscan2
- SLCO5A1 | c.2465C>T p.P822L | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs369446842; called by muse, mutect2, varscan2
- SPINK14 | c.170G>T p.C57F | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100810977; called by muse, mutect2, varscan2
- STK32B | c.225G>T p.M75I | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV99286284; called by muse, mutect2
- TFRC | c.1525A>G p.T509A | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.123); catalogued as COSV64055819; called by muse, mutect2
- TLR8 | c.2362G>A p.D788N (on ENST00000218032 / NM_138636.5; = p.D806N on NM_016610.4) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.642); catalogued as COSV99487112, COSV99487380; called by muse, mutect2, varscan2
- TM6SF2 | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV101231613; called by muse, mutect2, varscan2
- TUBGCP4 | c.213C>A p.H71Q | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV99539150; called by muse, mutect2, varscan2
- WDR27 | c.1753G>T p.D585Y | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100359149, COSV61216970; called by muse, mutect2
- XPO7 | c.1798T>G p.L600V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99381557; called by muse, mutect2, varscan2
- ZKSCAN3 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as COSV99356947, COSV99356997; called by muse, mutect2, varscan2
- ZNF280A | c.1400T>C p.I467T | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs764406269, COSV57481582; called by muse, mutect2
- KIR3DL1 | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.027); called by muse, mutect2
- SUPT20HL1 | c.2577G>T p.Q859H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- THAP12 | c.1832_1836del p.V611Gfs*14 | Frame Shift Del (DEL) | VAF 28/122 reads (23%) | called by mutect2, pindel, varscan2
- CRAMP1 | c.2691A>G p.P897= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs762690791, COSV99246124; called by muse, mutect2, varscan2
- GDF10 | c.303C>T p.S101= | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- GNAI1 | c.351C>T p.G117= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV100650554; called by muse, mutect2, varscan2
- IL15 | c.429T>C p.N143= | Silent (SNP) | VAF 30/235 reads (13%) | catalogued as COSV99650622; called by muse, mutect2, varscan2
- IRGQ | c.705G>T p.V235= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs1336054183, COSV100338187; called by muse, mutect2, varscan2
- KIF26B | c.1836G>A p.S612= | Silent (SNP) | VAF 52/296 reads (18%) | catalogued as rs1044237441, COSV100832754; called by muse, mutect2, varscan2
- KLHL18 | c.465G>C p.L155= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV99231048; called by muse, mutect2, varscan2
- MUC5AC | c.78T>C p.H26= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1336751540, COSV100650631; called by muse, mutect2, varscan2
- PSPH | c.417T>C p.F139= | Silent (SNP) | VAF 52/216 reads (24%) | catalogued as COSV51908810, COSV99304360; called by muse, mutect2, varscan2
- SHROOM3 | c.3462G>T p.T1154= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV56027871, COSV99934660; called by muse, mutect2, varscan2
- TNRC6C | c.3267C>T p.T1089= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100050160; called by muse, mutect2, varscan2
- VWA5A | c.591C>T p.S197= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs1365640470, COSV100795680; called by muse, mutect2, varscan2
